Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAEE, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAEE-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

GROSS:

Specimen status: Fresh

Specimen:

Liver: 10.0 x 4.5 x 4.3 cm, 103.7 gm

Gallbladder: 9.5 cm in length, 3.0 cm in diameter, 0.5 cm in wall thickness

Operation: Partial hepatectomy (segment 4) and cholecystectomy

Lesion:

[For liver]

A, well-defined mass (1.8 x 1.6 x 1.5 cm) at segment 4

Cut surface: Yellowish tan and solid

Gross type:

HCC: Nodular with perinodular extension

Resection margin: Not involved grossly (safety margin: 1.0 cm)

Satellite nodule: No

Portal vein invasion: No

Remaining parenchyma: Cirrhotic

[For gallbladder]

Two golden yellow polyps

Remaining gallbladder: Unremarkable

Representative sections submitted

Gross photo: Present

Blocks

T1-4 and TB, tumor x 5

NB and L, remaining liver x 2

GB, gallbladder x 1

MICROSCOPIC:

Hepatocellular carcinoma:

Edmondson-Steiner grade

The worst grade IV /IV

The major grade II /IV

Histologic type: Trabecular, pseudoglandular, compact

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: Partial capsule

Capsular infiltration: Yes

ICD O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
Op 5/20/14

[page 2 of 2]
Septum formation: Yes
Surgical resection margin invasion: No
Serosal invasion: No
Portal vein invasion: No
Microvessel invasion: No
Intrahepatic metastasis: No
Multicentric occurrence: No

NOT reported. Gross:

NOT reported. Gross:

Stomach, body, scopic, chronic gastritis, H. pylori, associated

Large intestine, rectosigmoid junction, ectomy, tubular adenoma, low grade, dysplasia

liver,ectomy,hepatocellular carcinoma

T56000, P10, M81703

gallbladder,ectomy,Chronic cholecystitis,cholesterolosis

T57000, P10, M43005, M55250

DIAGNOSIS:

Liver, segment 4, partial hepatectomy:

Hepatocellular carcinoma

Gallbladder, cholecystectomy:

Chronic cholecystitis

Cholesterolosis

Suggestion :

Source: NCI Genomic Data Commons file 6556a688-387a-4c9a-af9c-6ab39162204e (TCGA-DD-AAEE.D857BF5A-E2C6-4A6E-88CA-E8707E6FF3D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).